Somatic mutation profile of tumor specimen TCGA-04-1347-01A (aliquot TCGA-04-1347-01A-01W-0488-09) from TCGA case TCGA-04-1347, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 81.3 years (29,695 days).
Specimen TCGA-04-1347-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be173637-576a-4695-b83a-57406e5b5801.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1347-11A (Solid Tissue Normal), aliquot TCGA-04-1347-11A-01W-0487-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/818dbf34-acb1-4f65-bb95-bd00971f9179

The open-access MAF lists 148 somatic variants for this specimen: 114 protein-altering or splice-affecting, 30 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 30, Nonsense Mutation 11, Frame Shift Del 5, Splice Site 2, Intron 2, 5'UTR 2, In Frame Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.645T>A p.S215R | Missense Mutation (SNP) | VAF 86/96 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD941799, COSV52752255, COSV52783847, COSV52798196; called by muse, mutect2, varscan2
- ABCA12 | c.5195T>C p.I1732T (on ENST00000272895 / NM_173076.3; = p.I1414T on NM_015657.3) | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV55961133; called by muse, mutect2, varscan2
- ABI1 | c.1312G>T p.G438W | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100697971; called by muse, mutect2
- ACADL | c.173A>T p.D58V | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99284584; called by muse, mutect2
- ADAM29 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63664178; called by muse, mutect2, varscan2
- ADAM29 | c.1093A>G p.K365E | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV63664043; called by muse, mutect2, varscan2
- AMPD1 | c.1616T>C p.I539T | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV62416488; called by muse, mutect2, varscan2
- ANP32D | c.335_337del p.L112_E113delins* | Nonsense Mutation (DEL) | VAF 153/311 reads (49%) | catalogued as COSV56980536; called by mutect2, pindel, varscan2
- ASCC3 | c.2131C>T p.Q711* | Nonsense Mutation (SNP) | VAF 11/137 reads (8%) | catalogued as COSV61228642; called by muse, mutect2
- AURKC | c.781T>G p.S261A (on ENST00000302804 / NM_001015878.2; = p.S227A on NM_003160.3) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV57138801; called by muse, mutect2, varscan2
- BAG1 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 95/158 reads (60%) | catalogued as rs897821433, COSV65651658; called by muse, mutect2, varscan2
- BAG2 | c.278C>G p.T93S | Missense Mutation (SNP) | VAF 42/732 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as COSV58098442; called by muse, mutect2
- BLOC1S2 | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV58396340; called by muse, mutect2, varscan2
- BRAF | c.2030C>G p.S677* (on ENST00000288602 / NM_001374244.1; = p.S637* on NM_004333.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/170 reads (12%) | catalogued as COSV56199103; called by muse, mutect2, varscan2
- BRAF | c.1460G>T p.S487I (on ENST00000288602 / NM_001374244.1; = p.S447I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV104386540; called by muse, mutect2, varscan2
- BTBD3 | c.653C>G p.T218S | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.442); catalogued as COSV54779525; called by muse, mutect2, varscan2
- C11orf42 | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.325); catalogued as COSV56411819; called by muse, mutect2, varscan2
- C15orf48 | c.91G>C p.A31P | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV60223381; called by muse, mutect2, varscan2
- CCDC88A | c.4226A>G p.D1409G | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV55062703; called by muse, mutect2, varscan2
- CCPG1 | c.1697T>C p.F566S | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as rs1237981539, COSV51242027; called by muse, mutect2, varscan2
- CLDN17 | c.144A>T p.E48D | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746697944, COSV54523168; called by muse, mutect2, varscan2
- CPNE6 | c.1430C>G p.S477C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53744495; called by muse, mutect2, varscan2
- CSMD1 | c.3266G>A p.G1089E (on ENST00000520002; = p.G1088E on NM_033225.6) | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59331747; called by muse, mutect2, varscan2
- CYP2C18 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 113/587 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53670655, COSV53672567; called by muse, mutect2, varscan2
- DAGLA | c.2396G>C p.G799A | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.007); catalogued as COSV57196576; called by muse, mutect2, varscan2
- DCST2 | c.1169T>G p.I390S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55052086; called by muse, mutect2, varscan2
- DMXL1 | c.3653C>G p.S1218C | Missense Mutation (SNP) | VAF 71/106 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60707645, COSV60713018; called by muse, mutect2, varscan2
- DNAH10 | c.1460C>A p.A487D (on ENST00000409039; = p.A426D on NM_207437.3) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV68994878; called by muse, mutect2, varscan2
- DNALI1 | c.557A>G p.Y186C (on ENST00000296218; = p.Y164C on NM_003462.5) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV56170117; called by muse, mutect2, varscan2
- DROSHA | c.2789G>C p.R930T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV60776988; called by muse, mutect2, varscan2
- EXOC2 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as COSV57865654; called by muse, mutect2, varscan2
- EYA3 | c.335C>A p.T112N | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as COSV65816158, COSV65816805; called by muse, mutect2, varscan2
- FAT1 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.997); catalogued as COSV71674420; called by muse, mutect2, varscan2
- FGGY | c.1649A>G p.D550G | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV58034333; called by muse, mutect2, varscan2
- FKBP8 | c.662C>G p.A221G (on ENST00000222308 / NM_001308373.2; = p.A222G on NM_012181.5) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.254); catalogued as COSV55892618; called by muse, mutect2, varscan2
- FREM1 | c.1254G>T p.W418C | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63087347; called by muse, mutect2, varscan2
- GGT5 | c.1754G>T p.G585V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54070454; called by muse, mutect2, varscan2
- GOT1L1 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56875907; called by muse, mutect2, varscan2
- GRM3 | c.1486T>A p.S496T | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV64472686; called by muse, mutect2, varscan2
- H2BC8 | c.49A>G p.K17E | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.429); catalogued as COSV55127001; called by muse, mutect2, varscan2
- HEPHL1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59892398; called by muse, mutect2, varscan2
- HGD | c.177-1G>C p.X59_splice | Splice Site (SNP) | VAF 52/368 reads (14%) | catalogued as COSV52199812; called by muse, mutect2, varscan2
- HPSE | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.058); catalogued as rs780338532, COSV60987027; called by muse, mutect2, varscan2
- IGSF10 | c.3245C>G p.P1082R | Missense Mutation (SNP) | VAF 44/332 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.618); catalogued as COSV56781497, COSV99213320; called by muse, mutect2, varscan2
- INHBE | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1350720481; called by muse, mutect2
- KCNH2 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV51125881, COSV51127091; called by muse, mutect2, varscan2
- KRT25 | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.922); catalogued as COSV56445086; called by muse, mutect2, varscan2
- LCT | c.2911G>T p.V971L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.974); catalogued as COSV51550664, COSV51553974; called by muse, mutect2, varscan2
- MEGF10 | c.572G>C p.C191S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57250066; called by muse, mutect2, varscan2
- MFN2 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs545454816, COSV52422850; called by muse, mutect2, varscan2
- MMP7 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV52772263; called by muse, mutect2, varscan2
- MMP8 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV52632873, COSV99368594; called by muse, mutect2, varscan2
- MPP4 | c.406C>G p.P136A | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59631625; called by muse, mutect2, varscan2
- MRPS18B | c.96_97del p.C33Hfs*6 | Frame Shift Del (DEL) | VAF 42/194 reads (22%) | catalogued as rs749369142; called by mutect2, pindel, varscan2
- MTMR6 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as rs770125533, COSV67808073; called by muse, mutect2, varscan2
- MYEF2 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51048261, COSV51049708; called by muse, mutect2, varscan2
- NALCN | c.4493G>A p.R1498H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51935551; called by muse, varscan2
- NCAM2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53078750, COSV53110653; called by muse, mutect2, varscan2
- NEUROD4 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 254/1184 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54471998; called by muse, mutect2, varscan2
- NOTCH4 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs1304701623, COSV66681126; called by muse, mutect2, varscan2
- OR10X1 | c.161C>A p.T54N | Missense Mutation (SNP) | VAF 64/641 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV63767400; called by muse, mutect2
- OR5K2 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 103/392 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV71143237; called by muse, mutect2, varscan2
- PAK5 | c.1267C>G p.Q423E | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV62023084, COSV62028868; called by muse, mutect2, varscan2
- PDGFD | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 50/144 reads (35%) | catalogued as rs756756716, COSV56395135; called by muse, mutect2, varscan2
- PHC3 | c.1067A>C p.Q356P (on ENST00000494943 / NM_001308116.2; = p.Q368P on NM_024947.4) | Missense Mutation (SNP) | VAF 57/489 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV71948781; called by muse, mutect2, varscan2
- PLEKHA3 | c.55T>A p.W19R | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52294501; called by muse, mutect2, varscan2
- PLEKHF2 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.791); catalogued as COSV59541597; called by muse, mutect2, varscan2
- PTGFR | c.817G>T p.G273* | Nonsense Mutation (SNP) | VAF 58/253 reads (23%) | catalogued as COSV66115132, COSV66115387; called by muse, mutect2, varscan2
- PTPRN2 | c.751G>C p.A251P | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV67040418; called by muse, mutect2
- PZP | c.279C>G p.I93M | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV54361940; called by muse, mutect2, varscan2
- RING1 | c.329T>G p.I110S | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63002612; called by muse, mutect2, varscan2
- RNF114 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 20/156 reads (13%) | catalogued as rs773173342, COSV54869485, COSV99724797; called by muse, mutect2, varscan2
- RNF213 | c.6213C>G p.F2071L | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1035740297, COSV60399089; called by muse, mutect2, varscan2
- RNPS1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV57046814; called by muse, mutect2, varscan2
- SEC23A | c.1910T>C p.L637P | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56974592; called by muse, mutect2, varscan2
- SEL1L | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60920783; called by muse, mutect2, varscan2
- SEMA3D | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.021); catalogued as rs201113218; called by muse, mutect2
- SERPINB8 | c.393T>A p.H131Q | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.517); catalogued as COSV54639799; called by muse, mutect2
- SLC2A13 | c.1365C>A p.Y455* | Nonsense Mutation (SNP) | VAF 23/135 reads (17%) | catalogued as COSV55118802; called by muse, mutect2, varscan2
- SOX5 | c.2283A>T p.Q761H | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.648); catalogued as COSV58631614; called by muse, mutect2, varscan2
- SPINT1 | c.663G>C p.Q221H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59802024; called by muse, mutect2, varscan2
- TBX1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766608075, COSV60353710; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TLR1 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58304534; called by muse, mutect2, varscan2
- TMEM132D | c.2857G>T p.E953* | Nonsense Mutation (SNP) | VAF 57/438 reads (13%) | catalogued as COSV67159738, COSV67160626; called by muse, mutect2, varscan2
- TPO | c.1755C>A p.D585E | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368643878; called by muse, mutect2, varscan2
- TPX2 | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 139/426 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.038); catalogued as COSV55920004; called by muse, mutect2, varscan2
- TRIM13 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 28/76 reads (37%) | catalogued as COSV53949757; called by muse, mutect2, varscan2
- UNC45A | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs199668693; called by muse, varscan2
- VEZF1 | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 43/44 reads (98%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs745913326, COSV51969904; called by muse, mutect2, varscan2
- ZFP90 | c.812A>T p.E271V | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.114); catalogued as COSV68050991; called by muse, mutect2, varscan2
- ZSCAN31 | c.800A>T p.Y267F | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV60181009; called by muse, mutect2, varscan2
- ADGRF2 | c.1960dup p.I654Nfs*20 (on ENST00000296862 / NM_001368115.2; = p.I586Nfs*20 on NM_153839.7) | Frame Shift Ins (INS) | VAF 15/123 reads (12%) | called by mutect2, pindel, varscan2
- AK9 | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 26/442 reads (6%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.692); called by muse, mutect2
- ARHGAP29 | c.1627A>T p.S543C | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2
- ATP5PD | c.41T>A p.V14E | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); called by muse, mutect2
- C12orf42 | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DCC | c.1362_1404del p.A455Kfs*9 | Frame Shift Del (DEL) | VAF 28/151 reads (19%) | called by mutect2, pindel
- DOCK4 | c.4368_4383del p.F1456Lfs*4 | Frame Shift Del (DEL) | VAF 18/168 reads (11%) | called by mutect2, pindel
- DYNC1H1 | c.11395C>T p.Q3799* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2
- EIF2B4 | c.1049G>C p.W350S (on ENST00000347454 / NM_001034116.2; = p.W349S on NM_015636.3) | Missense Mutation (SNP) | VAF 17/478 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- GRIN2A | c.4196G>A p.S1399N | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- H2BC9 | c.325_354del p.K109_A118del | In Frame Del (DEL) | VAF 12/96 reads (13%) | called by mutect2, pindel
- LIN9 | c.737+1G>C p.X246_splice (on ENST00000366808 / NM_001270410.2; = p.X191_splice on NM_173083.3 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 13/139 reads (9%) | called by muse, mutect2, varscan2
- MRPL30 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 19/598 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2
- NCKAP5 | c.4553del p.P1518Qfs*3 | Frame Shift Del (DEL) | VAF 14/129 reads (11%) | called by mutect2, pindel, varscan2
- OR5K4 | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 86/888 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- OTOGL | c.664T>A p.Y222N (on ENST00000547103; = p.Y213N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARD3 | c.1561_1582del p.G521Ffs*4 | Frame Shift Del (DEL) | VAF 32/311 reads (10%) | called by mutect2, pindel
- POLR1H | c.144G>A p.R48= | Splice Region (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2, varscan2
- RYR2 | c.14840G>T p.R4947M | Missense Mutation (SNP) | VAF 13/271 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SMCHD1 | c.3211T>G p.F1071V | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2
- TERF2 | c.964C>G p.P322A | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); called by muse, mutect2
- USP47 | c.4032G>C p.Q1344H (on ENST00000399455 / NM_001372095.1; = p.Q1256H on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.365); called by muse, mutect2
- ZNF441 | c.1282T>C p.F428L | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- APP | c.84G>T p.L28= | Silent (SNP) | VAF 47/212 reads (22%) | catalogued as COSV60999187; called by muse, mutect2, varscan2
- ARHGEF11 | c.1425C>T p.A475= | Silent (SNP) | VAF 37/252 reads (15%) | catalogued as rs761961538, COSV63812929; called by muse, mutect2, varscan2
- ASPM | c.7725G>A p.K2575= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as COSV54130819; called by muse, mutect2
- BSND | c.285G>A p.Q95= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV64870735; called by muse, mutect2, varscan2
- CCT4 | c.1191G>A p.V397= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV66701520; called by muse, mutect2, varscan2
- CES1 | c.426G>T p.G142= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV62087271; called by mutect2, varscan2
- CHD7 | c.3687T>G p.L1229= | Silent (SNP) | VAF 74/522 reads (14%) | catalogued as COSV71111265; called by muse, mutect2, varscan2
- CNTNAP2 | c.3339C>T p.H1113= | Silent (SNP) | VAF 78/619 reads (13%) | called by muse, mutect2, varscan2
- CRADD | c.66G>T p.V22= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV60553806; called by muse, mutect2, varscan2
- CUBN | c.5523G>T p.T1841= | Silent (SNP) | VAF 141/692 reads (20%) | catalogued as rs767515084, COSV64715543, COSV64717173; called by muse, mutect2, varscan2
- DNAI2 | c.597C>T p.Y199= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV56759169; called by muse, mutect2, varscan2
- ESPN | c.1026C>T p.S342= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs753599663; called by muse, mutect2
- FCRL1 | c.705T>C p.S235= | Silent (SNP) | VAF 25/200 reads (13%) | catalogued as rs754478993, COSV63825524; called by muse, mutect2, varscan2
- GOLPH3 | c.885G>A p.A295= | Silent (SNP) | VAF 56/276 reads (20%) | catalogued as rs771157837, COSV54061024, COSV54061639; called by muse, mutect2, varscan2
- H4C12 | c.213G>A p.V71= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs764527111; called by muse, mutect2, varscan2
- HMCN1 | c.16410C>T p.C5470= | Silent (SNP) | VAF 43/425 reads (10%) | catalogued as COSV54904850; called by muse, mutect2, varscan2
- IL37 | c.294G>A p.L98= | Silent (SNP) | VAF 228/532 reads (43%) | catalogued as COSV54491350; called by muse, mutect2, varscan2
- KIR2DL1 | c.1035C>A p.V345= | Silent (SNP) | VAF 181/599 reads (30%) | catalogued as rs765912396; called by muse, mutect2, varscan2
- MYH8 | c.3396A>T p.R1132= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV67966087; called by muse, mutect2, varscan2
- MYSM1 | c.2202A>G p.E734= | Silent (SNP) | VAF 10/256 reads (4%) | called by muse, mutect2
- NR5A1 | c.1299C>A p.A433= | Silent (SNP) | VAF 19/20 reads (95%) | called by muse, mutect2
- PHLDB3 | c.1401G>A p.A467= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs373252899; called by muse, mutect2, varscan2
- PIK3CA | c.288A>G p.Q96= | Silent (SNP) | VAF 38/482 reads (8%) | catalogued as rs1307338981; called by muse, mutect2
- REV1 | c.993G>A p.T331= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV51485897; called by muse, mutect2, varscan2
- ROS1 | c.1677C>A p.G559= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV63856074; called by muse, mutect2, varscan2
- SESN2 | c.1125C>T p.Y375= | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as COSV53427820; called by muse, mutect2, varscan2
- USP43 | c.2364G>T p.R788= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV53303193; called by muse, mutect2, varscan2
- WNT1 | c.162A>G p.Q54= | Silent (SNP) | VAF 11/122 reads (9%) | called by muse, mutect2
- ZBTB43 | c.1362C>T p.Y454= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as rs776691831, COSV65094390; called by muse, mutect2, varscan2
- ZNF398 | c.117A>G p.A39= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV60065443; called by muse, mutect2, varscan2
- CALCR | c.51+2939C>T | Intron (SNP) | VAF 60/223 reads (27%) | catalogued as rs765001549, COSV64008472; called by muse, mutect2, varscan2
- DEFB118 | c.-1C>A | 5'UTR (SNP) | VAF 17/289 reads (6%) | catalogued as COSV99489231; called by muse, mutect2
- SKP2 | c.1062-1542G>A | Intron (SNP) | VAF 81/267 reads (30%) | catalogued as COSV57042518; called by muse, varscan2
- VPS11 | c.-1043C>G | 5'UTR (SNP) | VAF 9/39 reads (23%) | catalogued as COSV56185435; called by muse, mutect2, varscan2
